MMRF case MMRF_1231 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a2be2276-0af8-427d-8c64-f8ed8fa7a71a

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Dead; Days to death: 85 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.4 years (28,276 days); ISS stage: II; Days to last known disease status: 85 days; Days to last follow up: 85 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 85 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 85.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 5.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 39.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.481 mg/dL; Immunoglobulin G 76.8 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 5.02 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 16.1 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 11.8 g/dL; Glucose 4.79 mmol/L; C-Reactive Protein 0.18 mg/dL.
- Day 78: Hemoglobin 5.64 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 309 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.05 mmol/L; Glucose 4.02 mmol/L.

Other clinical attributes
- Day 1: Weight: 80 kg; Height: 158 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1231_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1231_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
